Somatic mutation profile of tumor specimen 0DOBTC from CCDI case PBCCDC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 4.5 years (1,652 days).
Specimen 0DOBTC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c082f3d-5359-46a0-850a-0cf76c500b6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOBSR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/600819a0-9ee6-4598-a1d2-07f87e07b3ec

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Nonsense Mutation 5, Intron 3, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRPPA | c.647C>A p.A216D | Missense Mutation (SNP) | VAF 122/1176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs387907160, CM123233; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR4 | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 399/800 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519792, COSV52800481, COSV52801581; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 58/508 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 139/809 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARFGEF2 | c.4724A>T p.K1575M | Missense Mutation (SNP) | VAF 38/1522 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV64213471; called by muse, mutect2
- CDH5 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 260/684 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58515766; called by muse, mutect2, varscan2
- CDK8 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 34/1041 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67419909; called by muse, mutect2
- DIS3L2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 146/638 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1022276697; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR37L1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 48/494 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.53); catalogued as rs776830420; called by muse, mutect2
- MR1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 193/558 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1368060940, COSV51580280; called by muse, mutect2, varscan2
- PHF20L1 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 116/1057 reads (11%) | catalogued as COSV55188987; called by muse, mutect2, varscan2
- PLEKHG4 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 192/585 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766535968, COSV58575150; called by muse, mutect2, varscan2
- SNX8 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 227/1273 reads (18%) | catalogued as rs199641540; called by muse, mutect2, varscan2
- TICRR | c.5297G>A p.G1766E | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs375925528; called by muse, mutect2, varscan2
- VCL | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 134/610 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1364541925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAALC | c.386G>T p.S129I (on ENST00000297574 / NM_001364874.1; = p.S94I on NM_024812.3) | Missense Mutation (SNP) | VAF 42/1496 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- CUX1 | c.1251G>T p.Q417H | Missense Mutation (SNP) | VAF 180/1388 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); called by mutect2, varscan2
- DDX42 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 288/1233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DENND4B | c.3337G>T p.A1113S | Missense Mutation (SNP) | VAF 176/340 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GCM2 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 183/474 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GMIP | c.438G>T p.M146I | Missense Mutation (SNP) | VAF 69/499 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- LMO7 | c.1992C>A p.S664R (on ENST00000357063; = p.S394R on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/1086 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MBOAT1 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 190/545 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMAA | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 81/442 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC19 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OGDHL | c.2757C>A p.I919= | Splice Region (SNP) | VAF 59/961 reads (6%) | called by muse, mutect2
- OR4N5 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 75/346 reads (22%) | called by muse, mutect2, varscan2
- PIAS2 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 235/677 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.514); called by mutect2, varscan2
- PNMA8B | c.217G>T p.V73F | Missense Mutation (SNP) | VAF 72/803 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.047); called by muse, mutect2
- SAMM50 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 30/537 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2
- SLC22A18 | c.1236G>A p.W412* | Nonsense Mutation (SNP) | VAF 102/1333 reads (8%) | called by muse, mutect2
- YIF1B | c.402+5G>T | Splice Region (SNP) | VAF 133/647 reads (21%) | called by muse, mutect2, varscan2
- ZNF628 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 56/750 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ZSWIM1 | c.1146C>A p.C382* | Nonsense Mutation (SNP) | VAF 30/771 reads (4%) | called by muse, mutect2
- AFAP1 | c.1044T>A p.V348= | Silent (SNP) | VAF 118/608 reads (19%) | called by muse, mutect2, varscan2
- ARID4A | c.546G>A p.V182= | Silent (SNP) | VAF 225/898 reads (25%) | catalogued as rs781236840; called by muse, mutect2, varscan2
- CTDNEP1 | c.681C>T p.T227= | Silent (SNP) | VAF 86/617 reads (14%) | catalogued as rs751047564, COSV56641802; called by muse, mutect2, varscan2
- FRY | c.3609C>T p.C1203= | Silent (SNP) | VAF 66/742 reads (9%) | catalogued as rs766566021, COSV66578801; called by muse, mutect2
- HAS1 | c.1170C>T p.N390= | Silent (SNP) | VAF 161/730 reads (22%) | catalogued as rs755573585, COSV99708400; called by muse, mutect2, varscan2
- PDZD2 | c.7065C>T p.S2355= | Silent (SNP) | VAF 394/849 reads (46%) | catalogued as rs753670602; called by muse, mutect2, varscan2
- SMPDL3B | c.597C>A p.T199= | Silent (SNP) | VAF 30/725 reads (4%) | called by muse, mutect2
- SYNE1 | c.22884C>A p.G7628= (on ENST00000367255 / NM_182961.4; = p.G7557= on NM_033071.3) | Silent (SNP) | VAF 53/932 reads (6%) | catalogued as COSV55074669; called by muse, mutect2
- ASPSCR1 | c.1354-1228G>T | Intron (SNP) | VAF 96/729 reads (13%) | called by muse, mutect2, varscan2
- KDM2B | c.3610+80C>T | Intron (SNP) | VAF 72/198 reads (36%) | called by muse, mutect2
- SLCO2B1 | c.781+73G>A | Intron (SNP) | VAF 47/201 reads (23%) | catalogued as rs749991063; called by muse, mutect2, varscan2
- TRIM52 | c.*373C>A | 3'UTR (SNP) | VAF 159/534 reads (30%) | called by muse, mutect2, varscan2
